Somatic mutation profile of tumor specimen TCGA-QR-A70W-01A (aliquot TCGA-QR-A70W-01A-12D-A35D-08) from TCGA case TCGA-QR-A70W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 40.0 years (14,613 days).
Specimen TCGA-QR-A70W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e794b586-0074-4972-8caa-362382f3bade.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70W-10B (Blood Derived Normal), aliquot TCGA-QR-A70W-10B-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a47f04a7-b19d-452a-9734-f7b9f84324b4

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KIAA1958 | c.1421_1430del p.L474Rfs*13 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- PI3 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- PLEKHG4B | c.1531A>G p.R511G (on ENST00000283426; = p.R867G on NM_052909.5) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- SAG | c.888C>T p.G296= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1312521946, COSV68592248; called by muse, mutect2, varscan2
